Somatic mutation profile of tumor specimen MMRF_1293_4_BM_CD138pos (aliquot MMRF_1293_4_BM_CD138pos_T1_KHS5U_L16532) from MMRF case MMRF_1293, project MMRF-COMMPASS (Multiple Myeloma CoMMpass Study). Sex at birth: male; Vital status: Alive; Primary diagnosis: Multiple myeloma; Tissue or organ of origin: Bone marrow; Age at diagnosis: 59.4 years (21,678 days).
Specimen MMRF_1293_4_BM_CD138pos: Sample type: Recurrent Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Recurrence; Specimen type: Bone Marrow NOS.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) daf63e6a-f0e9-4e5d-8fcd-52a18b138ed7.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MMRF_1293_2_PB_WBC (Blood Derived Normal), aliquot MMRF_1293_2_PB_WBC_C1_KBS5U_L05569; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/0bb386c9-c00b-45cb-a455-85b91039de7d

The open-access MAF lists 158 somatic variants for this specimen: 74 protein-altering or splice-affecting, 18 silent, 66 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 63, 3'UTR 39, Intron 21, Silent 18, Nonsense Mutation 4, 5'UTR 2, Splice Site 2, 5'Flank 2, Splice Region 2, Frame Shift Ins 1, RNA 1, 3'Flank 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- KRAS | c.38G>A p.G13D | Missense Mutation (SNP) | VAF 103/209 reads (49%) | hotspot (GDC flag); SIFT deleterious (0.04); PolyPhen benign (0.44); catalogued as rs112445441, CM125166, COSV55497357, COSV55497388, COSV55522580; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- A1CF | c.514G>A p.A172T | Missense Mutation (SNP) | VAF 74/148 reads (50%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.485); catalogued as rs775569138, COSV50987018; called by muse, mutect2, varscan2
- AC093246.1 | c.83G>A p.R28Q | Missense Mutation (SNP) | VAF 6/34 reads (18%) | catalogued as rs984975545, COSV51125252; called by muse, varscan2
- ACTL9 | c.995C>T p.A332V | Missense Mutation (SNP) | VAF 88/269 reads (33%) | SIFT tolerated (0.24); PolyPhen benign (0.058); catalogued as rs782533493, COSV61005098, COSV61006897; called by muse, mutect2, varscan2
- ANK2 | c.3293G>A p.R1098H | Missense Mutation (SNP) | VAF 36/84 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs764760708, COSV52170121, COSV52188897; called by muse, mutect2, varscan2
- ATG9B | c.2713G>A p.G905R | Missense Mutation (SNP) | VAF 17/61 reads (28%) | SIFT tolerated, low confidence (0.3); PolyPhen benign (0); catalogued as rs1193140397; called by muse, mutect2, varscan2
- BICD1 | c.1013G>T p.R338L | Missense Mutation (SNP) | VAF 24/56 reads (43%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.757); catalogued as rs183425481, COSV55675098; called by muse, mutect2, varscan2
- BPIFB3 | c.1234G>A p.A412T | Missense Mutation (SNP) | VAF 14/108 reads (13%) | SIFT tolerated (0.11); PolyPhen benign (0.022); catalogued as rs144741997; called by muse, mutect2, varscan2
- BSN | c.7796G>A p.S2599N | Missense Mutation (SNP) | VAF 21/233 reads (9%) | SIFT tolerated (0.22); PolyPhen benign (0.036); catalogued as rs367715844; called by muse, mutect2
- CCDC18 | c.3839G>C p.R1280T (on ENST00000343253 / NM_001306076.1; = p.R1281T on NM_206886.4) | Missense Mutation (SNP) | VAF 16/27 reads (59%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.639); catalogued as rs757562852; called by muse, mutect2, varscan2
- CDKL5 | c.1613C>T p.T538M | Missense Mutation (SNP) | VAF 92/93 reads (99%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.354); catalogued as rs1413837885; called by muse, mutect2, varscan2
- CSMD3 | c.3427C>A p.P1143T (on ENST00000297405 / NM_001363185.1; = p.P1039T on NM_052900.3) | Missense Mutation (SNP) | VAF 74/273 reads (27%) | SIFT tolerated (0.41); PolyPhen benign (0.001); catalogued as COSV52093613; called by muse, mutect2, varscan2
- DDR2 | c.1256T>C p.I419T | Missense Mutation (SNP) | VAF 4/40 reads (10%) | SIFT deleterious (0); PolyPhen possibly damaging (0.821); catalogued as rs1486535694; called by muse, mutect2, varscan2
- GPRC5C | c.130G>A p.A44T | Missense Mutation (SNP) | VAF 25/316 reads (8%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.364); catalogued as rs746270780; called by muse, mutect2
- H1-4 | c.308G>A p.G103D | Missense Mutation (SNP) | VAF 48/129 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV56799905, COSV56803909; called by muse, mutect2, varscan2
- HTR2C | c.727C>T p.R243* | Nonsense Mutation (SNP) | VAF 60/62 reads (97%) | catalogued as COSV52221996; called by muse, mutect2, varscan2
- IGHJ4 | c.44C>T p.S15L | Missense Mutation (SNP) | VAF 48/50 reads (96%) | PolyPhen benign (0.014); catalogued as rs555110696; called by muse, varscan2
- IRX4 | c.118G>A p.A40T | Missense Mutation (SNP) | VAF 40/166 reads (24%) | SIFT deleterious (0.05); PolyPhen benign (0.007); catalogued as rs754848816, COSV51474073; called by muse, mutect2, varscan2
- LRRC53 | c.2908dup p.T970Nfs*20 | Frame Shift Ins (INS) | VAF 10/58 reads (17%) | catalogued as rs1180095226; called by mutect2, pindel, varscan2
- MTO1 | c.170G>A p.R57Q | Missense Mutation (SNP) | VAF 51/164 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs757887848; called by muse, mutect2, varscan2
- OSBP2 | c.2262G>C p.M754I | Missense Mutation (SNP) | VAF 27/137 reads (20%) | SIFT tolerated (0.51); PolyPhen benign (0.163); catalogued as COSV100213165; called by muse, mutect2, varscan2
- PGAP2 | c.419-3C>T | Splice Region (SNP) | VAF 136/615 reads (22%) | catalogued as rs202073184; called by muse, mutect2, varscan2
- PPP2CB | c.443A>C p.D148A | Missense Mutation (SNP) | VAF 18/64 reads (28%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.717); catalogued as COSV55327989; called by muse, mutect2, varscan2
- SCUBE1 | c.484+1G>T p.X162_splice | Splice Site (SNP) | VAF 5/11 reads (45%) | catalogued as COSV51815538; called by muse, mutect2
- SOGA3 | c.2596C>T p.R866W | Missense Mutation (SNP) | VAF 62/135 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.937); catalogued as rs369861960; called by muse, mutect2, varscan2
- TAS2R1 | c.676G>A p.A226T | Missense Mutation (SNP) | VAF 43/185 reads (23%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.796); catalogued as rs145804099, COSV101225699; called by muse, mutect2, varscan2
- TGM4 | c.329A>G p.N110S | Missense Mutation (SNP) | VAF 38/59 reads (64%) | SIFT tolerated (0.43); PolyPhen benign (0.014); catalogued as rs202075944; called by muse, mutect2, varscan2
- TNK2 | c.101G>T p.R34L | Missense Mutation (SNP) | VAF 10/50 reads (20%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as COSV57370748, COSV57373730; called by muse, mutect2
- ZCCHC3 | c.410C>T p.A137V | Missense Mutation (SNP) | VAF 42/54 reads (78%) | SIFT tolerated (0.68); PolyPhen benign (0.003); catalogued as rs779001468; called by muse, varscan2
- APBB1 | c.2054T>A p.V685E | Missense Mutation (SNP) | VAF 9/104 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); called by muse, mutect2
- ARHGAP28 | c.806T>C p.I269T (on ENST00000383472 / NM_001366230.1; = p.I110T on NM_001010000.3) | Missense Mutation (SNP) | VAF 23/149 reads (15%) | SIFT tolerated (0.09); PolyPhen benign (0); called by muse, mutect2, varscan2
- ATP13A5 | c.151T>C p.F51L | Missense Mutation (SNP) | VAF 71/184 reads (39%) | SIFT tolerated (0.56); PolyPhen possibly damaging (0.717); called by muse, mutect2, varscan2
- CACNA1S | c.4201G>T p.E1401* | Nonsense Mutation (SNP) | VAF 44/135 reads (33%) | called by muse, mutect2, varscan2
- CGA | c.50T>G p.V17G | Missense Mutation (SNP) | VAF 114/120 reads (95%) | SIFT deleterious (0); PolyPhen possibly damaging (0.719); called by muse, mutect2, varscan2
- CHIA | c.927C>A p.F309L (on ENST00000343320; = p.F201L on NM_021797.4 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 44/92 reads (48%) | SIFT tolerated (0.07); PolyPhen benign (0.338); called by muse, mutect2, varscan2
- CLPTM1L | c.172T>G p.Y58D | Missense Mutation (SNP) | VAF 35/200 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); called by muse, mutect2, varscan2
- COL11A1 | c.3654+1G>C p.X1218_splice | Splice Site (SNP) | VAF 15/129 reads (12%) | called by muse, mutect2, varscan2
- COL11A2 | c.3764G>C p.G1255A (on ENST00000341947 / NM_080680.3; = p.G1148A on NM_080679.2) | Missense Mutation (SNP) | VAF 13/104 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); called by muse, mutect2, varscan2
- CYP2C18 | c.971A>G p.Q324R | Missense Mutation (SNP) | VAF 13/137 reads (9%) | SIFT tolerated (0.06); PolyPhen benign (0.314); called by muse, mutect2
- DGKB | c.193C>G p.L65V | Missense Mutation (SNP) | VAF 32/87 reads (37%) | SIFT tolerated (0.08); PolyPhen benign (0.017); called by muse, mutect2, varscan2
- DNAH14 | c.6156T>G p.F2052L (on ENST00000445597; = p.F2705L on NM_001367479.1) | Missense Mutation (SNP) | VAF 7/63 reads (11%) | SIFT tolerated (1); PolyPhen benign (0.005); called by muse, mutect2
- DRG2 | c.389G>A p.G130D | Missense Mutation (SNP) | VAF 8/51 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- FER1L6 | c.1305A>T p.K435N | Missense Mutation (SNP) | VAF 10/174 reads (6%) | SIFT tolerated (0.16); PolyPhen benign (0.212); called by muse, mutect2
- FES | c.2393C>T p.A798V | Missense Mutation (SNP) | VAF 6/58 reads (10%) | SIFT deleterious (0.03); PolyPhen benign (0.323); called by muse, mutect2, varscan2
- GPD1 | c.355A>T p.I119F | Missense Mutation (SNP) | VAF 11/80 reads (14%) | SIFT deleterious (0.03); PolyPhen benign (0.218); called by muse, mutect2, varscan2
- GPRASP1 | c.131C>T p.A44V | Missense Mutation (SNP) | VAF 4/83 reads (5%) | SIFT tolerated (0.08); PolyPhen benign (0.011); called by muse, mutect2
- HFM1 | c.2434T>A p.L812M | Missense Mutation (SNP) | VAF 20/43 reads (47%) | SIFT tolerated (1); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- IDE | c.1153+7A>C | Splice Region (SNP) | VAF 42/82 reads (51%) | called by muse, varscan2
- IGHV2-70 | c.118_135del p.T40_G45del | In Frame Del (DEL) | VAF 29/38 reads (76%) | called by mutect2, pindel, varscan2
- IGHV2-70D | c.253A>G p.K85E | Missense Mutation (SNP) | VAF 38/60 reads (63%) | SIFT deleterious (0.02); PolyPhen benign (0.003); called by muse, varscan2
- ITIH3 | c.2605G>T p.V869F | Missense Mutation (SNP) | VAF 30/256 reads (12%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.736); called by muse, mutect2, varscan2
- KLKB1 | c.705del p.N236Tfs*47 | Frame Shift Del (DEL) | VAF 73/209 reads (35%) | called by pindel, varscan2
- MAGI1 | c.1778C>A p.A593D | Missense Mutation (SNP) | VAF 41/157 reads (26%) | SIFT tolerated (0.49); PolyPhen possibly damaging (0.471); called by muse, mutect2, varscan2
- MED14 | c.1315G>C p.V439L | Missense Mutation (SNP) | VAF 51/53 reads (96%) | SIFT tolerated (0.75); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- METAP2 | c.1112A>G p.K371R | Missense Mutation (SNP) | VAF 24/55 reads (44%) | SIFT tolerated (0.71); PolyPhen benign (0.012); called by muse, mutect2
- MUC3A | c.8008A>G p.T2670A | Missense Mutation (SNP) | VAF 85/565 reads (15%) | SIFT deleterious, low confidence (0.02); PolyPhen possibly damaging (0.866); called by muse, mutect2, varscan2
- NYX | c.823G>C p.A275P | Missense Mutation (SNP) | VAF 30/105 reads (29%) | SIFT tolerated (0.26); PolyPhen possibly damaging (0.449); called by muse, mutect2, varscan2
- OR13C5 | c.411T>A p.S137R | Missense Mutation (SNP) | VAF 29/464 reads (6%) | SIFT deleterious (0.05); PolyPhen benign (0.012); called by muse, mutect2
- OR56A3 | c.410C>G p.P137R | Missense Mutation (SNP) | VAF 40/414 reads (10%) | SIFT deleterious (0); PolyPhen benign (0.027); called by muse, mutect2
- PARD3 | c.3628G>T p.E1210* | Nonsense Mutation (SNP) | VAF 41/76 reads (54%) | called by muse, mutect2, varscan2
- PCNX1 | c.4787T>G p.L1596* | Nonsense Mutation (SNP) | VAF 41/90 reads (46%) | called by muse, mutect2, varscan2
- REV3L | c.3538A>C p.K1180Q | Missense Mutation (SNP) | VAF 17/63 reads (27%) | SIFT tolerated, low confidence (0.14); PolyPhen benign (0.009); called by muse, mutect2, varscan2
- SELP | c.2390A>C p.K797T | Missense Mutation (SNP) | VAF 17/150 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.945); called by muse, mutect2, varscan2
- SLC12A1 | c.1106A>C p.N369T | Missense Mutation (SNP) | VAF 36/91 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- SMARCA5 | c.1328A>G p.K443R | Missense Mutation (SNP) | VAF 11/102 reads (11%) | SIFT tolerated (0.06); PolyPhen benign (0.029); called by muse, mutect2, varscan2
- SMARCAL1 | c.1556T>G p.L519R | Missense Mutation (SNP) | VAF 45/99 reads (45%) | SIFT deleterious (0); PolyPhen benign (0.18); called by muse, mutect2, varscan2
- SPINK5 | c.134C>T p.P45L | Missense Mutation (SNP) | VAF 16/78 reads (21%) | SIFT tolerated (0.06); PolyPhen benign (0.345); called by muse, mutect2, varscan2
- TNFRSF13B | c.487G>T p.V163F | Missense Mutation (SNP) | VAF 10/41 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.921); called by muse, mutect2, varscan2
- TNIK | c.1013C>A p.P338H | Missense Mutation (SNP) | VAF 24/57 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); called by muse, mutect2, varscan2
- WDR93 | c.1780G>A p.E594K | Missense Mutation (SNP) | VAF 5/84 reads (6%) | SIFT tolerated (0.31); PolyPhen benign (0.003); called by muse, mutect2
- ZAN | c.1733G>C p.S578T | Missense Mutation (SNP) | VAF 95/284 reads (33%) | SIFT tolerated (1); PolyPhen benign (0.12); called by muse, mutect2, varscan2
- ZNF169 | c.1802A>G p.E601G | Missense Mutation (SNP) | VAF 113/218 reads (52%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- ZNF497 | c.844G>A p.A282T | Missense Mutation (SNP) | VAF 11/84 reads (13%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.449); called by muse, mutect2, varscan2
- ZNF536 | c.2299A>C p.K767Q | Missense Mutation (SNP) | VAF 5/100 reads (5%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); called by muse, mutect2
- CDH4 | c.549C>T p.R183= | Silent (SNP) | VAF 15/28 reads (54%) | catalogued as rs1228050535; called by muse, mutect2, varscan2
- CYP2C18 | c.969C>T p.V323= | Silent (SNP) | VAF 12/134 reads (9%) | catalogued as COSV99608202; called by muse, mutect2
- DOCK2 | c.4335C>G p.S1445= | Silent (SNP) | VAF 32/113 reads (28%) | called by muse, mutect2, varscan2
- ETFB | c.699C>T p.R233= | Silent (SNP) | VAF 48/145 reads (33%) | called by muse, mutect2, varscan2
- GRB10 | c.1050C>T p.G350= (on ENST00000398812; = p.G304= on NM_001001549.3) | Silent (SNP) | VAF 29/83 reads (35%) | called by muse, mutect2, varscan2
- IGHD2-2 | c.22C>T p.L8= | Silent (SNP) | VAF 18/19 reads (95%) | catalogued as rs781865993; called by muse, mutect2, varscan2
- IGKC | c.150T>G p.G50= | Silent (SNP) | VAF 38/38 reads (100%) | called by muse, varscan2
- KCNC1 | c.249C>T p.C83= | Silent (SNP) | VAF 20/60 reads (33%) | catalogued as COSV56391450; called by muse, mutect2, varscan2
- KRT5 | c.507C>T p.R169= | Silent (SNP) | VAF 23/44 reads (52%) | catalogued as rs200658792, COSV52859976; called by muse, mutect2, varscan2
- MMP2 | c.306C>T p.C102= | Silent (SNP) | VAF 66/129 reads (51%) | catalogued as rs201679510, CM161166; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- OR1M1 | c.477C>T p.H159= | Silent (SNP) | VAF 105/334 reads (31%) | catalogued as rs551740717; called by muse, mutect2, varscan2
- OR2AJ1 | c.813T>C p.D271= | Silent (SNP) | VAF 26/246 reads (11%) | called by muse, mutect2, varscan2
- OR2J3 | c.702C>T p.T234= | Silent (SNP) | VAF 13/138 reads (9%) | catalogued as rs1467256696; called by muse, mutect2
- PRDM10 | c.2892T>C p.D964= | Silent (SNP) | VAF 20/133 reads (15%) | called by muse, mutect2, varscan2
- RFNG | c.435G>C p.V145= | Silent (SNP) | VAF 50/131 reads (38%) | called by muse, mutect2, varscan2
- TFPT | c.450C>T p.A150= | Silent (SNP) | VAF 30/88 reads (34%) | called by muse, mutect2, varscan2
- TRIB3 | c.306G>A p.Q102= | Silent (SNP) | VAF 30/40 reads (75%) | called by mutect2, varscan2
- TUBGCP6 | c.3789G>T p.R1263= | Silent (SNP) | VAF 11/101 reads (11%) | catalogued as COSV50560611; called by muse, mutect2, varscan2
- ABCD3 | c.-53C>T | 5'UTR (SNP) | VAF 13/30 reads (43%) | catalogued as rs555210827; called by muse, mutect2, varscan2
- ABL2 | c.*5243T>A | 3'UTR (SNP) | VAF 45/150 reads (30%) | called by muse, mutect2, varscan2
- AGBL3 | c.2343-5715T>G | Intron (SNP) | VAF 80/129 reads (62%) | catalogued as rs537988721; called by muse, mutect2
- AGBL5 | c.*348T>G | 3'UTR (SNP) | VAF 17/27 reads (63%) | called by muse, mutect2, varscan2
- ALDH5A1 | c.*995C>T | 3'UTR (SNP) | VAF 11/123 reads (9%) | called by muse, mutect2, varscan2
- ANK1 | c.5395-1114C>T | Intron (SNP) | VAF 12/123 reads (10%) | catalogued as rs565535918, COSV55900629; called by muse, mutect2
- ARHGEF15 | c.*1360C>A | 3'UTR (SNP) | VAF 47/85 reads (55%) | called by muse, mutect2, varscan2
- BMP6 | c.*1184_*1186del | 3'UTR (DEL) | VAF 26/46 reads (57%) | called by pindel, varscan2
- BRWD1 | c.6571+3215T>C | Intron (SNP) | VAF 43/117 reads (37%) | called by muse, mutect2, varscan2
- C11orf71 | c.343+158T>G | Intron (SNP) | VAF 15/20 reads (75%) | called by muse, mutect2
- C11orf71 | c.343+61T>C | Intron (SNP) | VAF 110/162 reads (68%) | called by muse, mutect2, varscan2
- C6orf141 | c.*148+371T>C | Intron (SNP) | VAF 46/56 reads (82%) | called by muse, mutect2, varscan2
- CACNA1B | c.*1510G>T | 3'UTR (SNP) | VAF 35/97 reads (36%) | called by muse, mutect2, varscan2
- CADM2 | c.*23T>C | 3'UTR (SNP) | VAF 108/317 reads (34%) | catalogued as rs1388231729; called by muse, mutect2, varscan2
- CERS5 | c.1029+1421T>C | Intron (SNP) | VAF 3/17 reads (18%) | called by muse, varscan2
- CLIP1 | c.3966+1558A>G | Intron (SNP) | VAF 14/69 reads (20%) | catalogued as rs1566066884; called by muse, mutect2, varscan2
- CLRN1 | chr3:150972856 C>T | 5'Flank (SNP) | VAF 11/134 reads (8%) | called by muse, mutect2
- COG5 | c.2312+41G>A | Intron (SNP) | VAF 4/51 reads (8%) | called by muse, mutect2
- CTNNA1 | c.105+303G>C | Intron (SNP) | VAF 8/139 reads (6%) | called by muse, mutect2
- DHX33 | c.*1440G>T | 3'UTR (SNP) | VAF 10/45 reads (22%) | called by muse, mutect2, varscan2
- DNAH14 | c.3052-22626C>G | Intron (SNP) | VAF 15/146 reads (10%) | called by muse, mutect2, varscan2
- DOCK6 | c.45-112C>T | Intron (SNP) | VAF 3/30 reads (10%) | called by muse, mutect2
- DPP6 | c.*612A>T | 3'UTR (SNP) | VAF 40/95 reads (42%) | called by muse, mutect2, varscan2
- DUSP6 | chr12:89353214 ins T | 5'Flank (INS) | VAF 16/38 reads (42%) | called by mutect2, pindel, varscan2
- ELAPOR1 | c.2973+427G>A | Intron (SNP) | VAF 12/22 reads (55%) | called by muse, mutect2, varscan2
- EPCAM | c.76+85T>C | Intron (SNP) | VAF 32/70 reads (46%) | called by muse, mutect2, varscan2
- GLO1 | c.*885A>G | 3'UTR (SNP) | VAF 38/127 reads (30%) | catalogued as rs1329038617; called by muse, mutect2, varscan2
- GOLGA1 | c.*4G>A | 3'UTR (SNP) | VAF 61/209 reads (29%) | called by muse, mutect2, varscan2
- HIBCH | c.*105A>G | 3'UTR (SNP) | VAF 19/32 reads (59%) | called by muse, mutect2, varscan2
- HLA-A | c.*148del | 3'UTR (DEL) | VAF 71/289 reads (25%) | called by pindel, varscan2
- HPS5 | c.3329+11T>C | Intron (SNP) | VAF 34/156 reads (22%) | called by muse, mutect2, varscan2
- HYDIN2 | n.10942C>T | RNA (SNP) | VAF 24/290 reads (8%) | called by muse, mutect2
- IL17D | c.*279A>G | 3'UTR (SNP) | VAF 36/69 reads (52%) | called by muse, mutect2, varscan2
- INSC | c.*761T>C | 3'UTR (SNP) | VAF 14/70 reads (20%) | called by muse, mutect2, varscan2
- KCNJ10 | c.*285C>G | 3'UTR (SNP) | VAF 16/220 reads (7%) | called by muse, mutect2
- KLF13 | c.*3046A>G | 3'UTR (SNP) | VAF 41/95 reads (43%) | called by muse, mutect2, varscan2
- KLF3 | c.*2020G>A | 3'UTR (SNP) | VAF 22/48 reads (46%) | called by muse, mutect2, varscan2
- LRRC55 | c.*1453G>A | 3'UTR (SNP) | VAF 12/186 reads (6%) | called by muse, mutect2
- MSR1 | c.1033+3906dup | Intron (INS) | VAF 25/77 reads (32%) | called by mutect2, pindel, varscan2
- MYO7A | c.*432G>C | 3'UTR (SNP) | VAF 12/170 reads (7%) | called by muse, mutect2
- NDUFAF1 | c.759+611C>T | Intron (SNP) | VAF 11/26 reads (42%) | called by muse, mutect2, varscan2
- NIT1 | chr1:161125366 G>T | 3'Flank (SNP) | VAF 11/90 reads (12%) | called by muse, mutect2, varscan2
- NLRC5 | c.4154+224A>T | Intron (SNP) | VAF 71/140 reads (51%) | called by muse, mutect2, varscan2
- OTX1 | c.*214G>A | 3'UTR (SNP) | VAF 59/110 reads (54%) | catalogued as rs1035097087; called by muse, mutect2, varscan2
- P4HB | c.*565G>A | 3'UTR (SNP) | VAF 13/137 reads (9%) | called by muse, mutect2, varscan2
- PDE4DIP | c.518+229G>T | Intron (SNP) | VAF 37/381 reads (10%) | called by muse, mutect2, varscan2
- PLXNA4 | c.*6937del | 3'UTR (DEL) | VAF 10/44 reads (23%) | catalogued as rs200299501; called by mutect2, varscan2
- PSORS1C1 | c.-43G>A | 5'UTR (SNP) | VAF 18/253 reads (7%) | called by muse, mutect2
- RCE1 | c.*242G>A | 3'UTR (SNP) | VAF 15/96 reads (16%) | called by muse, mutect2, varscan2
- RFX6 | c.*91A>G | 3'UTR (SNP) | VAF 3/35 reads (9%) | called by muse, mutect2
- RNF115 | c.*420A>G | 3'UTR (SNP) | VAF 25/78 reads (32%) | catalogued as rs1197904396; called by muse, mutect2, varscan2
- RPS10 | c.*423C>T | 3'UTR (SNP) | VAF 61/218 reads (28%) | called by muse, mutect2, varscan2
- RPTN | c.*777G>T | 3'UTR (SNP) | VAF 14/38 reads (37%) | called by muse, mutect2, varscan2
- SEMA3E | c.*3279C>A | 3'UTR (SNP) | VAF 18/37 reads (49%) | called by muse, mutect2, varscan2
- SRRM4 | c.*1733C>T | 3'UTR (SNP) | VAF 51/108 reads (47%) | catalogued as rs1419700230; called by muse, mutect2, varscan2
- STC2 | c.506+76G>A | Intron (SNP) | VAF 19/52 reads (37%) | catalogued as rs767834711; called by muse, mutect2
- SV2B | c.*4525C>T | 3'UTR (SNP) | VAF 8/182 reads (4%) | catalogued as rs868649906; called by muse, mutect2
- SYNPO2L | c.*284C>T | 3'UTR (SNP) | VAF 16/35 reads (46%) | called by muse, mutect2, varscan2
- TEPSIN | c.122-76G>A | Intron (SNP) | VAF 9/37 reads (24%) | called by muse, mutect2, varscan2
- TMEM33 | c.*1593A>G | 3'UTR (SNP) | VAF 15/28 reads (54%) | called by muse, mutect2, varscan2
- TTC9 | c.*3338G>A | 3'UTR (SNP) | VAF 21/46 reads (46%) | called by muse, mutect2, varscan2
- VGLL3 | c.*8114dup | 3'UTR (INS) | VAF 48/145 reads (33%) | called by mutect2, pindel, varscan2
- WNT3A | c.*435A>T | 3'UTR (SNP) | VAF 17/107 reads (16%) | called by muse, mutect2, varscan2
- ZBTB42 | c.*608_*609insCG | 3'UTR (INS) | VAF 15/44 reads (34%) | called by pindel, varscan2
- ZNF141 | c.*9378A>T | 3'UTR (SNP) | VAF 48/97 reads (49%) | called by muse, varscan2
- ZNF24 | c.*4478T>G | 3'UTR (SNP) | VAF 16/29 reads (55%) | called by muse, mutect2, varscan2
